Surgical pathology report (de-identified scan), TCGA case TCGA-H2-A2K9, project TCGA-THCA (Thyroid Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-H2-A2K9-01A (Primary Tumor).

[page 1 of 2]
Final Surgical Pathology Report

1CD-0-3

Carcinoma, papillary, thyroid

8260/3

Site: thyroid, NOS C73.9

lu 8/24/11

Procedure:

Diagnosis

A. Thyroid, total thyroidectomy:

Multifocal papillary carcinoma, involving the right and left lobes, largest focus 2.8 cm.

B. Central cervical lymph nodes, resection:

Metastatic carcinoma involving 11 of 14 lymph nodes (11/14).

Microscopic Description:

Microscopic examination performed.

A.

Histologic type: Papillary carcinoma, papillary and follicular variant, multifocal

Primary tumor (pT): The tumor is multifocal. The largest focus is 2.8 cm, located in the right lobe

Margins of resection: Extremely close, less than 0.5 mm

Vascular invasion: Present

Regional lymph nodes (pN): Positive as described below, pN1

Distant metastasis (pM): Cannot be evaluated by the specimen, pMX

Other findings: None

B. The central cervical lymph nodes demonstrate metastatic carcinoma in 11 of 14 lymph nodes. Many of the metastases are present in the form of a few subcapsular nests of malignant cells.

Immunohistochemistry for pankeratin was performed on blocks B1 through B3 to highlight the metastatic cells. The largest focus is 3.5 mm.

4X2, 20

Specimen

A. Total thyroid - silk marks left upper pole

B. Cervical-central node dissection

Clinical Information

Papillary carcinoma of the thyroid

Gross Description

Received fresh in a container labeled total thyroid - silk marks the upper pole is a complete thyroidectomy. It measures 9 x 7.5 x 4.7 m in greatest dimensions. A silk stitch marks the left upper pole. The specimen is inked and serially sectioned. The left lobe contains a firm white gritty tumor measuring 1.2 x 1 x 0.8 cm. The isthmus is unremarkable. The right lobe contains a well-circumscribed soft yellow-tan nodule measuring 2.8 x 2.5 x 2.0 cm. A portion of this nodule is submitted for tissue procurement. The thyroid is entirely submitted in 20 blocks. BLOCK SUMMARY A1 - A5 left lobe; A6 - A8 isthmus; A 9 - A.20 right lobe.

[page 2 of 2]
B. Received in formalin labeled "central cervical node dissection" is a 2.4 x 2.0 x 1.2 cm aggregate of fragmented soft, lobulated golden yellow adipose tissue and slightly rubbery tan-pink tissues measuring up to 0.6 cm in greatest dimension. Multiple slightly rubbery tan-pink tissue using keeping with lymph nodes measuring up to 0.8 cm are present. The specimen is entirely submitted in 4 blocks as labeled. Summary: 1 and 2-5 whole lymph nodes per cassette; 3-one bisected lymph node; 4-residual tissue.

Source: NCI Genomic Data Commons file 9408f331-43c7-427f-af35-bfae7205127d (TCGA-H2-A2K9.726162B8-E14A-49DE-8164-70EDB6609EC8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).